Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6705, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6705-01A (Primary Tumor).

[page 1 of 2]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Gastrectomy
Tumor site: Stomach
Tumor size: 8 x 0 x 0 cm
Tumor features: Ulcerated
Histologic type: Adenocarcinoma
Histologic grade: Poorly differentiated
Tumor extent: Subserosa
Lymph nodes: 9/12 positive for metastasis (Greater and lesser omentum 9/12)
Lymphatic invasion: Not specified
Venous invasion: Present
Perineural invasion: Not specified
Margins: Uninvolved
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file ff353496-a213-48ac-9443-2d2644102c6f (TCGA-BR-6705.E333B11F-3071-4DFD-9992-B03DB7A86952.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).